Somatic mutation profile of tumor specimen TCGA-EJ-7330-01A (aliquot TCGA-EJ-7330-01A-11D-2114-08) from TCGA case TCGA-EJ-7330, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 68.6 years (25,050 days).
Specimen TCGA-EJ-7330-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a66ca664-659c-456f-8225-2aa05c534ee0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-7330-10A (Blood Derived Normal), aliquot TCGA-EJ-7330-10A-01D-2114-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0fd27218-4e17-4190-b8ed-84c900e6bfb3

The open-access MAF lists 43 somatic variants for this specimen: 32 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 9, Splice Site 3, Nonsense Mutation 2, RNA 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXA1 | c.758T>C p.M253T | Missense Mutation (SNP) | VAF 5/38 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51643604, COSV51643636, COSV51645087; called by muse, varscan2
- SPOP | c.399C>A p.F133L | Missense Mutation (SNP) | VAF 19/176 reads (11%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen possibly damaging (0.718); catalogued as COSV61652814, COSV61652918; called by muse, mutect2, varscan2
- AC097636.1 | c.103A>T p.K35* | Nonsense Mutation (SNP) | VAF 20/70 reads (29%) | catalogued as COSV71309460; called by muse, mutect2, varscan2
- AGA | c.334A>G p.I112V | Missense Mutation (SNP) | VAF 50/392 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.214); catalogued as rs925345330, COSV52805940; called by muse, mutect2, varscan2
- AHI1 | c.537G>T p.E179D | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV55626019; called by muse, mutect2, varscan2
- ALDH18A1 | c.1366C>T p.R456C | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs763868475, COSV64662417; called by muse, mutect2, varscan2
- ATP12A | c.90G>T p.K30N | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.346); catalogued as COSV54513558, COSV54514666; called by muse, mutect2, varscan2
- CABP2 | c.409G>A p.V137M | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as COSV53708602; called by muse, mutect2, varscan2
- CDC37 | c.197G>C p.R66T | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.129); catalogued as COSV55767930; called by muse, mutect2, varscan2
- CDH11 | c.1399C>A p.H467N | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV51757506; called by muse, mutect2
- CDK13 | c.2543+2T>C p.X848_splice | Splice Site (SNP) | VAF 34/145 reads (23%) | catalogued as COSV51698294; called by muse, mutect2, varscan2
- CNGB3 | c.1279T>G p.F427V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV60687810; called by muse, mutect2
- COL4A2 | c.733G>A p.V245I | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs371879428; called by muse, mutect2, varscan2
- CRISP2 | c.515+1G>A p.X172_splice | Splice Site (SNP) | VAF 24/180 reads (13%) | catalogued as rs147611117; called by mutect2, varscan2
- ENO1 | c.1177-2A>G p.X393_splice | Splice Site (SNP) | VAF 4/41 reads (10%) | catalogued as COSV52303386; called by muse, mutect2
- GPC6 | c.490T>C p.F164L | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65506295, COSV65538971; called by muse, mutect2
- HELQ | c.1062T>A p.N354K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55024762; called by muse, varscan2
- KCNAB1 | c.604G>T p.E202* (on ENST00000490337 / NM_172160.3; = p.E191* on NM_003471.3) | Nonsense Mutation (SNP) | VAF 17/201 reads (8%) | catalogued as COSV100204307, COSV56743821; called by muse, mutect2
- KCTD14 | c.100G>C p.V34L | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.631); catalogued as COSV62001254; called by muse, mutect2, varscan2
- MUC5AC | c.14836G>A p.V4946M | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs372686872, COSV64369303; called by muse, mutect2, varscan2
- NPHS1 | c.2441A>C p.Y814S | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62287264; called by muse, mutect2, varscan2
- OR4X2 | c.132C>A p.S44R | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV56582965; called by muse, mutect2, varscan2
- PRXL2C | c.641A>G p.H214R | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV64450116; called by muse, mutect2, varscan2
- RB1 | c.676T>C p.F226L | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.272); catalogued as COSV57302507; called by muse, mutect2, varscan2
- SCN8A | c.5551T>G p.F1851V | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61979388; called by muse, mutect2, varscan2
- THRA | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs746290948, COSV52842004; called by muse, mutect2, varscan2
- TNRC18 | c.1807C>T p.R603C | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1395831028, COSV68087367; called by muse, mutect2
- TRIM29 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs771869031, COSV59279371; called by muse, mutect2, varscan2
- WIF1 | c.215A>G p.K72R | Missense Mutation (SNP) | VAF 5/145 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1324624395, COSV54130051, COSV54130847; called by muse, mutect2
- ZMIZ1 | c.1495C>T p.P499S | Missense Mutation (SNP) | VAF 48/367 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV57893024; called by muse, mutect2, varscan2
- ZNF92 | c.1175C>T p.T392M (on ENST00000328747 / NM_152626.4; = p.T323M on NM_007139.4) | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs775659581, COSV60873743; called by muse, mutect2, varscan2
- SGF29 | c.210del p.E71Rfs*49 | Frame Shift Del (DEL) | VAF 17/98 reads (17%) | called by mutect2, pindel, varscan2
- ANGPT4 | c.939G>A p.T313= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs755790516, COSV67921183; called by muse, varscan2
- CAND1 | c.2853T>C p.V951= | Silent (SNP) | VAF 15/97 reads (15%) | catalogued as COSV73389576; called by muse, mutect2, varscan2
- DDC | c.285C>T p.C95= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as rs748439275, COSV63564715; called by muse, mutect2
- EPB41L5 | c.2184A>G p.L728= | Silent (SNP) | VAF 37/222 reads (17%) | catalogued as COSV55350847; called by muse, mutect2, varscan2
- HAPLN3 | c.450C>T p.D150= | Silent (SNP) | VAF 33/143 reads (23%) | catalogued as rs369076877, COSV62084735; called by muse, mutect2, varscan2
- KIFAP3 | c.1377A>G p.V459= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV100846861, COSV63032675; called by muse, mutect2, varscan2
- MAP1A | c.1761A>G p.E587= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV55807727; called by muse, mutect2, varscan2
- PTCHD3 | c.432G>A p.A144= | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as rs571645965, COSV101438810, COSV71256641; called by muse, mutect2, varscan2
- RPP38 | c.45G>A p.K15= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as rs753831222, COSV65381931; called by muse, mutect2, varscan2
- ARPP19P1 | n.264del | RNA (DEL) | VAF 18/82 reads (22%) | called by mutect2, pindel*, varscan2
- PVRIG | chr7:100224019 C>T | 3'Flank (SNP) | VAF 20/167 reads (12%) | catalogued as rs775570000, COSV52780826; called by muse, mutect2, varscan2
